Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A5XK, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A5XK-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Pheochromocytoma¹¹⁰⁵ 8760/0
Site Adrenal gland NOS
C74.9
JW 4/2/13

Diagnosis:

Adrenal gland, right, adrenalectomy

Histologic tumor type: pheochromocytoma

Tumor size (greatest dimension): 6 x 6 x 3.8 cm

Tumor gland weight: 101 g

Extent of invasion:

Extra-adrenal tissues: not involved

Lymphovascular: not involved

Blood vascular: not involved

Tumor necrosis: not identified

Surgical margins: not involved

Status of adrenal gland away from tumor: no significant histologic abnormality

Lymph nodes: none sampled

AJCC Stage: pT2 pNx pMx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information

Clinical History:

Pheochromocytoma. CIS: Rads: 7.1 cm diameter enhancing right adrenal mass, adenoma versus adrenal cortical carcinoma versus pheochromocytoma. No regional lymphadenopathy, other intraabdominal masses, contralateral mass, or liver lesions.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right adrenal gland" and holds a 101, 6 x 6 x 3.8 cm ovoid, firm

[page 2 of 2]
HPV (discrepancy)		✓
Time Discrepancy (days)		✓

Source: NCI Genomic Data Commons file 1f645822-90a4-424c-bd65-8c3b75b733ab (TCGA-QT-A5XK.B8F0F027-4F5C-4142-99F1-776747B7E86A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).